Somatic mutation profile of tumor specimen TCGA-AG-A02G-01A (aliquot TCGA-AG-A02G-01A-01W-A00E-09) from TCGA case TCGA-AG-A02G, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.4 years (24,259 days).
Specimen TCGA-AG-A02G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cab92d85-c536-4c8f-bd92-290524c8761f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A02G-10A (Blood Derived Normal), aliquot TCGA-AG-A02G-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ad32a94-8691-4259-a272-e366e79e9134

The open-access MAF lists 46 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Nonsense Mutation 3, Splice Region 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 35/46 reads (76%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2
- NR3C2 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 84/274 reads (31%) | catalogued as rs1131691568, CM066154, COSV60987901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 70/89 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACAN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs201105250, COSV61362457; called by muse, mutect2, varscan2
- BIN1 | c.1745G>T p.G582V (on ENST00000316724 / NM_001320642.1; = p.G443V on NM_004305.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119428; called by muse, mutect2
- CSRP2 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as rs762670612, COSV60702849, COSV60703473; called by muse, mutect2, varscan2
- DMD | c.6572G>A p.R2191Q | Missense Mutation (SNP) | VAF 228/279 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756238158, COSV58919631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTD1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs753802514, COSV66279944; called by muse, mutect2, varscan2
- ERCC6 | c.3416C>T p.S1139F | Missense Mutation (SNP) | VAF 139/418 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63388535; called by muse, mutect2, varscan2
- GALNT16 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV61886374; called by muse, mutect2, varscan2
- GPLD1 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57755396; called by muse, mutect2, varscan2
- GRM5 | c.1392A>G p.G464= | Splice Region (SNP) | VAF 49/151 reads (32%) | catalogued as COSV100551351, COSV59610194; called by muse, mutect2, varscan2
- INTS6 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 161/278 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV60878781; called by muse, mutect2, varscan2
- ITGAV | c.2784C>A p.Y928* | Nonsense Mutation (SNP) | VAF 59/72 reads (82%) | catalogued as rs199793723, COSV53714130, COSV53719622, COSV99654145; called by muse, mutect2, varscan2
- KBTBD4 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs771167882, COSV55453632; called by muse, mutect2, varscan2
- LEPROT | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 297/402 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs746314508, COSV60757086, COSV60763472; called by muse, mutect2, varscan2
- MTTP | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1366920959; called by muse, mutect2, varscan2
- NALCN | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 331/1052 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51942581, COSV51953892; called by muse, mutect2, varscan2
- NRG2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs749464757, COSV56833457, COSV56834647; called by muse, mutect2, varscan2
- NT5C2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as rs776259786, COSV58417073; called by muse, mutect2, varscan2
- OR1A1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 327/387 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs371610534; called by muse, mutect2, varscan2
- OR2T4 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 199/429 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as COSV100822440, COSV63543621, COSV63544272; called by muse, mutect2, varscan2
- PA2G4 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57569099; called by muse, mutect2, varscan2
- PCDHA3 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV65367926; called by muse, mutect2, varscan2
- PCED1B | c.332C>G p.S111W | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as COSV71395331; called by muse, mutect2, varscan2
- PPFIA2 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs756585090, COSV61036849; called by muse, mutect2, varscan2
- RNF40 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs758836306, COSV61215289; called by muse, mutect2, varscan2
- RUFY3 | c.578T>G p.F193C | Missense Mutation (SNP) | VAF 158/270 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56914546; called by muse, mutect2, varscan2
- SALL3 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs778334113, COSV73306140; called by muse, mutect2, varscan2
- SOCS5 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 106/191 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs149307689; called by muse, mutect2, varscan2
- TET1 | c.6071G>A p.R2024Q | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1169730805, COSV65385710; called by muse, mutect2, varscan2
- THBS1 | c.3332G>A p.R1111H | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370392120; called by muse, mutect2, varscan2
- THSD7B | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs375232957; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 10/92 reads (11%) | catalogued as rs754083634; called by mutect2, varscan2
- AMER1 | c.1206del p.D403Mfs*4 | Frame Shift Del (DEL) | VAF 77/121 reads (64%) | called by mutect2, pindel, varscan2
- CTSV | c.367A>G p.K123E | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by mutect2, varscan2
- PTN | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 75/608 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TIGD3 | c.95C>G p.S32W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKAP9 | c.9348T>G p.S3116= (on ENST00000359028; = p.S3092= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 140/241 reads (58%) | catalogued as COSV62349140; called by muse, mutect2, varscan2
- CYP11A1 | c.1173C>T p.S391= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs751829411, COSV51432644; called by muse, mutect2, varscan2
- ELF4 | c.1812C>T p.R604= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV57453183; called by muse, mutect2, varscan2
- FLT1 | c.2670C>T p.N890= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs550669773, COSV56730854; called by muse, mutect2, varscan2
- KIAA0408 | c.636G>T p.G212= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as COSV100847029; called by muse, mutect2
- PREX2 | c.2415G>A p.K805= | Silent (SNP) | VAF 85/163 reads (52%) | catalogued as COSV55777794; called by muse, mutect2, varscan2
- ZNF462 | c.6063C>T p.R2021= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs376720857; called by muse, mutect2, varscan2
- DPF3 | c.871+2995C>T | Intron (SNP) | VAF 27/74 reads (36%) | catalogued as rs780037884, COSV63500713; called by muse, mutect2, varscan2
